Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5739, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5739-01A (Primary Tumor).

Diagnosis

1. Tumor-free preprostatic fatty tissue.
2. Six tumor-free lymph nodes on the right.
3. Two tumor-free lymph nodes on the left.
4. Predominantly moderately differentiated adenocarcinoma of the prostate with spread in the left prostate lobe and infiltration of the left-sided perivesicular fatty tissue. Predominance in the left rectolateral peripheral zone. Maximum tumor diameter 1.2 cm. Focal perineural tumor spread. Tumor-free seminal vesicles and preparation margins.

TCGA-CH-5739

Remark

Tumor classification: pT3a pN0 (0/8); L0, V0, Gleason 3+4 = 7 (Gleason 4: 10%), complete local resection.

Source: NCI Genomic Data Commons file a5a4990d-f2f8-4272-b47f-11339ffbbf56 (TCGA-CH-5739.6DB82B14-85E4-40C4-9827-A588C4A25CE8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).